Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3731, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3731-01A (Primary Tumor).

Diagnosis/diagnoses:

Rectal resection material shows a moderately differentiated adenocarcinoma (G2) located in the distal rectum, with superficial infiltration of the perirectal fatty tissue (pT3) and tumor-free oral, aboral and perirectal resection margins.

Follow-up report:

Following acetone clarification, 34 lymph nodes in the pericolic fatty tissue bordering the tumor were prepared, measuring up to 1.2 cm.

Amongst these, three metastatic infiltrations of the previously diagnosed adenocarcinoma and colon carcinoma were identified.

In conclusion and in summary a stage of pT3 pN1 (3/34) is established.

Source: NCI Genomic Data Commons file d9787486-8525-434d-9954-284b79cc9a25 (TCGA-AG-3731.0C404036-04F3-45C0-A319-48203D8A380E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).